Somatic mutation profile of tumor specimen TCGA-XF-AAN3-01A (aliquot TCGA-XF-AAN3-01A-11D-A42E-08) from TCGA case TCGA-XF-AAN3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.4 years (27,909 days).
Specimen TCGA-XF-AAN3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bce0967-40f9-486c-afe1-5aa7a8fe5de2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAN3-10A (Blood Derived Normal), aliquot TCGA-XF-AAN3-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dab5378-a8ec-4cc1-8f55-aa4e91538c8c

The open-access MAF lists 180 somatic variants for this specimen: 120 protein-altering or splice-affecting, 55 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 55, Nonsense Mutation 6, 3'UTR 2, RNA 2, Nonstop Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 6/12 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 23/64 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56472222; called by muse, mutect2
- ADORA3 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.073); catalogued as COSV53985030; called by muse, mutect2, varscan2
- AGTPBP1 | c.3281G>C p.G1094A (on ENST00000357081 / NM_001330701.2; = p.G1054A on NM_015239.2) | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61268835; called by muse, mutect2
- ANK1 | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs771237247, COSV55873730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3B1 | c.2824G>C p.E942Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54876850; called by muse, mutect2, varscan2
- APBB1IP | c.54G>C p.E18D | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63301635, COSV63302632; called by muse, mutect2, varscan2
- ATF7IP | c.2759C>G p.S920C | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV99662307; called by muse, mutect2
- BAZ2A | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.588); catalogued as COSV51632076; called by muse, mutect2, varscan2
- BNC2 | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV66141061; called by muse, mutect2, varscan2
- BPIFA1 | c.745G>C p.G249R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV62823927, COSV62825003; called by muse, mutect2, varscan2
- C2CD3 | c.5663A>T p.K1888M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV58089851; called by muse, mutect2, varscan2
- CACNA1D | c.3413T>C p.I1138T (on ENST00000350061 / NM_001128840.3; = p.I1158T on NM_000720.4) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs146540139, COSV55443529; called by muse, mutect2, varscan2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by muse, mutect2, varscan2
- CATSPER4 | c.1183C>G p.R395G | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773246457, COSV58792353; called by muse, mutect2, varscan2
- CBLN4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV50352129, COSV50354495; called by muse, mutect2, varscan2
- CCDC170 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV53336914; called by muse, mutect2, varscan2
- CD244 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as COSV59236255; called by muse, mutect2
- CDK12 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV70999416; called by muse, mutect2, varscan2
- CDON | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV54995327; called by muse, mutect2, varscan2
- CHD1 | c.3694C>G p.P1232A | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV52337461; called by muse, mutect2, varscan2
- CLDN11 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50355114; called by muse, mutect2
- CLGN | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV57773292; called by mutect2, varscan2
- COL5A1 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1030105888, COSV65665427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CP | c.1831G>C p.D611H | Missense Mutation (SNP) | VAF 113/226 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV52829174; called by muse, mutect2, varscan2
- CRIP2 | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781803780, COSV61273961; called by muse, mutect2, varscan2
- CRPPA | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554347337, COSV67904313; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYBG2 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV57483925; called by muse, mutect2, varscan2
- DDX58 | c.2777G>C p.*926Sext*33 | Nonstop Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100008797; called by muse, mutect2, varscan2
- DENND2A | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52048046; called by muse, mutect2, varscan2
- DEPDC4 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV100147453; called by muse, mutect2
- DHX40 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52066091; called by muse, varscan2
- DMD | c.7364C>T p.A2455V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1416125216, COSV58893519; called by muse, mutect2
- DNAJC14 | c.1561C>A p.L521M | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV54477785; called by muse, mutect2, varscan2
- DOCK3 | c.2438G>C p.R813T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.87); catalogued as COSV56504739; called by muse, mutect2, varscan2
- DPP10 | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV59666352, COSV59673998, COSV59676988; called by muse, mutect2, varscan2
- DSG4 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV57388581, COSV57389351; called by muse, mutect2, varscan2
- DYNC1H1 | c.9675G>C p.K3225N | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64134625; called by muse, mutect2, varscan2
- EIF4A2 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV60623750; called by muse, mutect2, varscan2
- ENKD1 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV54666027; called by muse, mutect2, varscan2
- ERBB2 | c.3037G>C p.D1013H | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV54064041; called by muse, mutect2, varscan2
- FANCM | c.5044G>C p.D1682H | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV57497553; called by muse, mutect2
- FASN | c.2897C>A p.P966H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.338); catalogued as COSV60750858; called by muse, mutect2, varscan2
- GNA15 | c.417G>C p.W139C | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53584873, COSV53585093; called by muse, mutect2
- GPBP1L1 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.124); catalogued as rs1402923801, COSV51967129; called by muse, mutect2, varscan2
- GPR6 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51571100, COSV51573424; called by muse, mutect2, varscan2
- H3C8 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as COSV59952626; called by muse, mutect2, varscan2
- HDGF | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV61975643; called by muse, mutect2, varscan2
- HEATR1 | c.4261G>C p.E1421Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV63979877, COSV63981993; called by muse, mutect2, varscan2
- HLCS | c.2132G>A p.G711D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99293728; called by muse, mutect2
- HTR5A | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1204412791, COSV55280731; called by muse, mutect2, varscan2
- IFTAP | c.666A>T p.*222Cext*18 | Nonstop Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100531437; called by muse, mutect2, varscan2
- IGF2BP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as rs1454481322, COSV51729363; called by muse, mutect2, varscan2
- IK | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs758632408, COSV70257414; called by muse, mutect2, varscan2
- ITPR2 | c.7135G>C p.E2379Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101189985, COSV101190271; called by muse, mutect2
- ITPR2 | c.5248G>C p.D1750H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67265104; called by muse, mutect2, varscan2
- KRTAP6-2 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | PolyPhen possibly damaging (0.836); catalogued as COSV58181952; called by muse, mutect2, varscan2
- LEXM | c.1157C>G p.S386* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100827813; called by muse, mutect2, varscan2
- LIMCH1 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58274245; called by muse, mutect2
- MADD | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV60620804; called by muse, mutect2, varscan2
- MED12L | c.6274C>T p.L2092F | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); catalogued as COSV56369475; called by muse, mutect2, varscan2
- MPP5 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99907518; called by muse, mutect2, varscan2
- MTMR7 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51663270; called by muse, mutect2, varscan2
- MYBL1 | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as rs1272063509, COSV101576619; called by muse, mutect2, varscan2
- NACA2 | c.312T>A p.F104L | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV71713088; called by muse, mutect2, varscan2
- NAP1L1 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs1235021865, COSV53873533; called by muse, mutect2, varscan2
- NOD1 | c.1977C>G p.I659M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs749945912, COSV56110901; called by muse, mutect2, varscan2
- NUP214 | c.3656C>T p.S1219L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV63907806; called by muse, mutect2, varscan2
- OAF | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV61108857; called by muse, mutect2, varscan2
- OR2M5 | c.352A>T p.M118L | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV63545740; called by muse, mutect2, varscan2
- OR4A5 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV60521623; called by muse, mutect2, varscan2
- OR51L1 | c.900G>T p.Q300H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as COSV58623968; called by muse, mutect2, varscan2
- OR52E4 | c.790C>G p.R264G | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57623964, COSV57624022; called by muse, mutect2
- OR5A1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574597111, COSV57375852; called by muse, mutect2, varscan2
- OVCH1 | c.2687G>A p.G896E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as COSV100548391, COSV58959874; called by muse, mutect2, varscan2
- PACC1 | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV54786316, COSV54786674; called by muse, mutect2, varscan2
- PCDHB15 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV50859515; called by muse, mutect2, varscan2
- PELP1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.202); catalogued as COSV52585913; called by muse, mutect2, varscan2
- PJA2 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63271855; called by muse, mutect2, varscan2
- PLA2R1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51775251; called by muse, mutect2, varscan2
- POLE | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV57674812; called by muse, mutect2, varscan2
- PPP1R12B | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs368133673, COSV61113573; called by muse, mutect2, varscan2
- PSG7 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 31/355 reads (9%) | catalogued as COSV68444313; called by muse, mutect2
- PTPRH | c.2810C>T p.S937L | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs761395502, COSV54742917; called by muse, mutect2, varscan2
- RCAN2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.995); catalogued as COSV57814804; called by muse, mutect2, varscan2
- RELL2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.978); catalogued as COSV51836633; called by muse, mutect2, varscan2
- RPL10 | c.507G>C p.K169N | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV50010007, COSV50010138; called by muse, mutect2, varscan2
- RPS6KC1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV65297355; called by muse, mutect2, varscan2
- RYR3 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747174943, COSV66778985; called by muse, mutect2, varscan2
- RYR3 | c.10573G>A p.E3525K (on ENST00000389232; = p.E3526K on NM_001036.6) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as rs1360069428, COSV101215123, COSV66809059; called by muse, mutect2
- SCAF11 | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV65475127; called by muse, mutect2, varscan2
- SCARF2 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV56731184; called by muse, mutect2, varscan2
- SERPINA12 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs1466384071, COSV57942342; called by muse, mutect2, varscan2
- SF3B1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV59207586; called by muse, mutect2, varscan2
- SFRP4 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs769250207; called by muse, mutect2
- SH3YL1 | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV62155511; called by muse, mutect2, varscan2
- SHANK2 | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53586757, COSV99573924; called by muse, mutect2, varscan2
- SLC2A3 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV50000679; called by muse, mutect2, varscan2
- SMARCA5 | c.2809A>C p.I937L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as COSV51642449; called by muse, mutect2, varscan2
- SP140 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV59446640; called by muse, mutect2, varscan2
- SPACA1 | c.418C>G p.H140D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV52759079; called by muse, mutect2, varscan2
- SPATA1 | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55361216; called by muse, mutect2, varscan2
- SPECC1 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV54953165; called by muse, mutect2, varscan2
- SUGP2 | c.2828C>T p.S943F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs535452264, COSV58255522; called by muse, mutect2, varscan2
- SUPT16H | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV53522391; called by muse, mutect2, varscan2
- SYNE1 | c.3871G>C p.D1291H (on ENST00000367255 / NM_182961.4; = p.D1298H on NM_033071.3) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV54914476; called by muse, mutect2, varscan2
- TRIO | c.8257G>T p.D2753Y | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59988685; called by muse, mutect2, varscan2
- TSC22D2 | c.2206C>G p.L736V | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62622190; called by muse, mutect2
- TTC14 | c.2068C>T p.H690Y | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs567854542, COSV56009561; called by muse, mutect2
- TUBG1 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV52220587; called by muse, mutect2, varscan2
- VPS13B | c.3790C>G p.P1264A | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62134054, COSV62138828; called by muse, varscan2
- WBP11 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99660956; called by muse, mutect2, varscan2
- XIRP2 | c.2709T>A p.S903R (on ENST00000628543; = p.S1078R on NM_152381.6) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54684302; called by muse, mutect2, varscan2
- ZCCHC7 | c.1616G>C p.R539T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV60954680; called by muse, mutect2, varscan2
- ZNF443 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.155); catalogued as rs1191248159, COSV56890455; called by muse, mutect2, varscan2
- ZNF471 | c.1094G>A p.W365* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV100340945; called by muse, mutect2, varscan2
- ZNF502 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs200013409, COSV56072524, COSV56072697; called by muse, mutect2, varscan2
- ZP2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs202010660, COSV54812236; called by muse, mutect2, varscan2
- ABCA7 | c.2733G>C p.L911= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99566825; called by muse, mutect2
- ABCC11 | c.2805C>T p.P935= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs750997339, COSV62321472; called by muse, mutect2, varscan2
- AICDA | c.93C>T p.Y31= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs777729620, CM064965, COSV57563560; called by muse, mutect2, varscan2
- AMIGO3 | c.213C>T p.N71= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1221057060, COSV57537622; called by muse, mutect2, varscan2
- APOBEC3A | c.599G>A p.*200= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1426866198, COSV99970271; called by muse, mutect2, varscan2
- ASB10 | c.1344C>T p.L448= (on ENST00000420175 / NM_001142459.2; = p.L433= on NM_080871.4) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV51994434; called by muse, mutect2, varscan2
- ASPRV1 | c.6G>A p.G2= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs777385150, COSV57227466; called by muse, mutect2, varscan2
- ATP9A | c.1026C>T p.I342= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1356928117, COSV58763498; called by muse, mutect2, varscan2
- CENPO | c.150C>G p.T50= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV53229334; called by muse, mutect2, varscan2
- CEP70 | c.165C>T p.L55= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV53874367; called by muse, mutect2, varscan2
- CLPTM1 | c.234C>T p.A78= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV61611107; called by muse, mutect2, varscan2
- CNTN1 | c.2037C>T p.F679= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as COSV61636500; called by muse, mutect2, varscan2
- COL5A1 | c.213G>A p.P71= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs775666676, COSV65665420; called by muse, mutect2, varscan2
- CUEDC1 | c.99C>G p.L33= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100804827; called by muse, mutect2
- DAGLB | c.747C>T p.I249= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV51702416; called by muse, mutect2, varscan2
- DBH | c.225G>A p.Q75= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1303141361, COSV55039782, COSV99707973; called by muse, mutect2, varscan2
- DCLRE1C | c.21G>A p.Q7= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs939562272, COSV63181972; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOK1 | c.613C>T p.L205= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2
- DYNC1H1 | c.8691G>A p.L2897= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV64134618; called by muse, mutect2, varscan2
- DYNC1H1 | c.8805G>C p.L2935= | Silent (SNP) | VAF 86/286 reads (30%) | catalogued as COSV64134621; called by muse, mutect2, varscan2
- EPHA10 | c.747C>A p.G249= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100140211; called by muse, varscan2
- EPHX2 | c.630G>A p.L210= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV66843986; called by muse, mutect2, varscan2
- ERBB2 | c.2745G>C p.L915= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs1228364579, COSV54064024; called by muse, mutect2, varscan2
- ERCC6 | c.762G>A p.Q254= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV63388035; called by muse, mutect2, varscan2
- ESX1 | c.654C>T p.F218= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV65423926; called by muse, mutect2
- FAM47A | c.21G>A p.Q7= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV100650126, COSV60494217; called by muse, mutect2, varscan2
- FBXO47 | c.27C>T p.F9= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV65241211; called by muse, mutect2, varscan2
- FNDC11 | c.630C>T p.V210= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as rs754985671, COSV64442422; called by muse, mutect2, varscan2
- GRIN2D | c.1149G>A p.V383= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV54377152; called by muse, mutect2, varscan2
- HCN3 | c.1119C>T p.F373= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs1206127813, COSV64233363; called by muse, mutect2, varscan2
- HPS3 | c.1809G>A p.E603= | Silent (SNP) | VAF 84/152 reads (55%) | catalogued as COSV56052864, COSV56056842; called by muse, mutect2, varscan2
- HSPA12A | c.642C>T p.F214= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV65020902; called by muse, mutect2, varscan2
- JAKMIP2 | c.660C>T p.I220= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV54598057; called by muse, mutect2, varscan2
- MROH2B | c.1098C>T p.L366= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV68181284; called by muse, mutect2, varscan2
- MRPS7 | c.600G>A p.L200= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs750449573, COSV55452902; called by muse, mutect2, varscan2
- MYO1D | c.1065C>T p.I355= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as rs147504723; called by muse, mutect2, varscan2
- NOD1 | c.2145C>G p.L715= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV56110891; called by muse, mutect2, varscan2
- NUP93 | c.1938G>C p.L646= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs1485238251, COSV57428796; called by muse, mutect2, varscan2
- OGDHL | c.2547G>A p.L849= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV65101075; called by muse, mutect2, varscan2
- OR13J1 | c.831C>G p.L277= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV65069367; called by muse, mutect2, varscan2
- PCLO | c.1983G>A p.L661= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs780354940, COSV100427221; called by muse, mutect2
- PTPRN2 | c.1668C>T p.F556= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV67023782; called by muse, mutect2, varscan2
- SKIDA1 | c.219C>T p.I73= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV71610456; called by muse, mutect2, varscan2
- SLC27A5 | c.1095C>G p.S365= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV54018159; called by muse, mutect2, varscan2
- SLC29A4 | c.366G>A p.L122= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV51872933; called by muse, mutect2, varscan2
- SNX3 | c.159C>T p.V53= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100018132; called by muse, mutect2
- SRI | c.498G>A p.L166= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV56000285; called by muse, mutect2, varscan2
- STMN2 | c.539G>A p.*180= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1290627138, COSV99625985; called by muse, mutect2, varscan2
- TANC1 | c.2625C>G p.L875= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV55083532; called by muse, mutect2, varscan2
- TM9SF4 | c.1230G>A p.K410= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV54104610; called by muse, mutect2, varscan2
- TUBGCP2 | c.1713C>T p.D571= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs145076825; called by muse, mutect2, varscan2
- USH2A | c.60G>A p.L20= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100230566, COSV56331576; called by muse, mutect2, varscan2
- VPS41 | c.1284C>G p.L428= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV59645989; called by muse, mutect2, varscan2
- ZAN | c.7758A>G p.Q2586= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV61805473; called by muse, mutect2, varscan2
- ZNF831 | c.1224C>T p.I408= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1319255247, COSV64042548, COSV64044350; called by muse, mutect2
- LAMA4 | c.195+136C>T | Intron (SNP) | VAF 18/59 reads (31%) | catalogued as COSV54568732; called by muse, mutect2, varscan2
- SDHA | c.*2G>A | 3'UTR (SNP) | VAF 21/87 reads (24%) | catalogued as COSV99372311; called by muse, mutect2, varscan2
- SNORD64 | n.32G>A | RNA (SNP) | VAF 20/95 reads (21%) | catalogued as rs1013740183; called by muse, mutect2, varscan2
- SSPOP | n.3281G>A | RNA (SNP) | VAF 6/19 reads (32%) | catalogued as rs752647290, COSV100023095; called by muse, varscan2
- VMP1 | c.*1389G>A | 3'UTR (SNP) | VAF 81/177 reads (46%) | called by muse, mutect2, varscan2
